Somatic mutation profile of tumor specimen TARGET-10-PARUBN-09A (aliquot TARGET-10-PARUBN-09A-01D) from TARGET case TARGET-10-PARUBN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,586 days).
Specimen TARGET-10-PARUBN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a7dcd5c-7034-4e93-817f-2df0e1d8021e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARUBN-10A (Blood Derived Normal), aliquot TARGET-10-PARUBN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6401cd51-00f3-41a6-9239-8564924fdb49

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 2, Silent 2, Intron 2, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRK | c.4277G>A p.R1426H (on ENST00000368215 / NM_001291984.2; = p.R1427H on NM_002844.4) | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.168); catalogued as rs1202657000, COSV63908880; called by muse, mutect2, varscan2
- HELQ | c.1509dup p.E504* | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- LYPD1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- SPEN | c.10904_10905insCC p.E3636Lfs*24 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | called by mutect2, pindel, varscan2
- TRO | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- COPS5 | c.837G>A p.Q279= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- F11 | c.423G>A p.T141= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs771153790, COSV53006665; called by muse, mutect2, varscan2
- CREB3L1 | c.1032-39G>A | Intron (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- RBFOX1 | c.351+152620G>A | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- TEX15 | chr8:30849111 A>G | 5'Flank (SNP) | VAF 27/111 reads (24%) | called by muse, mutect2, varscan2
- TMEM177 | chr2:119685861 GAAGTAA>AG | 3'Flank (DEL) | VAF 12/65 reads (18%) | called by pindel, varscan2*
